Somatic mutation profile of tumor specimen TCGA-KC-A4BR-01A (aliquot TCGA-KC-A4BR-01A-32D-A257-08) from TCGA case TCGA-KC-A4BR, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 76.0 years (27,741 days).
Specimen TCGA-KC-A4BR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 25eb6db7-41e6-4d20-b7cb-08932457d033.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KC-A4BR-10A (Blood Derived Normal), aliquot TCGA-KC-A4BR-10A-01D-A25A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/475d9af2-ae38-409b-ae25-34d1dc855810

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 3, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H2BC8 | c.8A>T p.E3V | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.041); catalogued as COSV99773262; called by muse, mutect2
- LRP1B | c.12221C>A p.T4074K | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101257744; called by muse, mutect2
- TAS1R2 | c.1871C>T p.P624L | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs1250505995, COSV64743790; called by muse, mutect2, varscan2
- ERCC2 | c.1149G>A p.L383= | Silent (SNP) | VAF 4/44 reads (9%) | catalogued as COSV55541704; called by muse, mutect2
- SPATA21 | c.1074G>T p.R358= | Silent (SNP) | VAF 9/204 reads (4%) | catalogued as COSV100131003; called by muse, mutect2
